TCGA case TCGA-ER-A198 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea240769-e51c-45f5-a131-ba123e598622

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Dead; Days to death: 1,544 days (4.2 years).

Diagnoses (5)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: Progression; Age at diagnosis: 46.3 years (16,916 days); Days to diagnosis: 376 days (1.0 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 4 of this record; Age at diagnosis: 45.3 years (16,540 days); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 45.3 years (16,540 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic N: NX; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dacarbazine; Initial disease status: Progressive Disease; Days to treatment start: 426 days (1.2 years); Days to treatment end: 517 days (1.4 years); Prescribed dose: 400; Prescribed dose units: mg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
5. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectosigmoid junction; Classification of tumor: Prior primary; AJCC staging edition: 6th.

Follow-up (2 entries)
- Day 0 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,544 days (4.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ER-A198-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ER-A198-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-ER-A198-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ER-A198-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 10; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Other  Specify; Melanoma primary count: 1; Site of primary tumor other: Right Axilla.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Rectal Adenocarcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 89.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior adenocarcinoma of the rectosigmoid junction. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,544 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,544 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ER-A198-06A-11D-A194-01): tumor purity 0.79, ploidy 2, whole-genome doublings 0.
